Gene-level copy-number profile of tumor specimen HTMCP-03-06-02068-01A from CGCI case HTMCP-03-06-02068, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 59.1 years (21,573 days).
Specimen HTMCP-03-06-02068-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c38f6c3e-3bd8-46f2-a39b-9a110248e05c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02068-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/13cd44f8-b3e4-43a4-9274-54c7bb2ecfd0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 1,129; copy number 2: 15,742; copy number 3: 18,087; copy number 4: 10,494; copy number 5: 3,402; copy number 6: 7,160; copy number 7: 1,407; copy number 8: 284; copy number 9: 236; copy number 10: 413; copy number 12: 29.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:132,643,286–132,671,579, 2 genes (within-gene range 0–2): LYPD1, AC010974.1.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr11:4,329,865–4,330,449, 1 gene: SSU72P3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,369 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:144,523,860–196,065,235, 1,342 genes, copy number 7–8 (broad region; genes not listed).
- chr2:83,657,735–84,350,774, 5 genes, copy number 7: RNU6-1312P, CRLF3P3, ST6GALNAC2P1, FUNDC2P2, AC106874.1.
- chr2:87,221,113–87,767,359, 13 genes, copy number 10 (within-gene range 6–10): CENPNP1, LINC01955, DBF4P3, AC068279.2, IGKV3OR2-268, AC068279.1, LINC01943, CYTOR, AC133644.2, AC133644.1, PAFAH1B1P1, MIR4435-1, RPS14P5.
- chr3:153,067,278–197,627,906, 756 genes, copy number 7–10 (broad region; genes not listed).
- chr3:197,660,565–198,123,232, 21 genes, copy number 9: AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1.
- chr5:42,423,439–42,721,878, 1 gene, copy number 7 (within-gene range 6–7): GHR.
- chr5:42,729,138–45,895,970, 55 genes, copy number 7: AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr9:65,189,995–65,193,610, 1 gene, copy number 10: BMS1P12.
- chr11:33,376,108–33,674,102, 1 gene, copy number 7 (within-gene range 2–7): KIAA1549L.
- chr11:33,450,646–34,147,670, 17 genes, copy number 7: AL133399.1, AL049629.1, C11orf91, AL049629.2, CD59, FBXO3, FBXO3-DT, AC113192.3, AC113192.2, LINC02722, AC113192.1, LINC02721, LMO2, AC132216.1, AC090469.1, CAPRIN1, NAT10.
- chr11:34,404,663–35,138,032, 13 genes, copy number 7: AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1.
- chr11:35,251,205–36,697,867, 28 genes, copy number 7: SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, KRT18P14, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973, AC129502.1, COMMD9, PRR5L, AC087277.1, AC087277.2, AC009656.1, TRAF6, AC061999.1, RAG1, RAG2, IFTAP, AC104042.1.
- chr14:18,333,726–18,650,966, 17 genes, copy number 7: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11.
- chr14:21,903,077–22,526,906, 97 genes, copy number 9–12 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 12: TRAC.
- chr14:45,891,087–46,501,903, 1 gene, copy number 7: LINC00871.

Autosomal genes at a single copy (total copy number 1): 1,129. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
